Somatic mutation profile of tumor specimen 0DI3NI from CCDI case PBBVIA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Urinary system, NOS; Age at diagnosis: 14.5 years (5,301 days).
Specimen 0DI3NI: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ca56f0f-d388-4d9e-883b-fd8a6e08d2d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI3JI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9894b81-b7da-4b96-a8d0-8f9786b78454

The open-access MAF lists 33 somatic variants for this specimen: 27 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 3, Intron 2, Nonsense Mutation 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 199/540 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- CCT6A | c.778G>C p.V260L | Missense Mutation (SNP) | VAF 134/391 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV51908039; called by muse, mutect2, varscan2
- CD300H | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 153/393 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1307092075; called by muse, mutect2, varscan2
- DNAH5 | c.9506G>A p.R3169H | Missense Mutation (SNP) | VAF 165/476 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489264409; called by muse, mutect2, varscan2
- EPHX4 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 160/495 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs1557880119; called by muse, mutect2, varscan2
- FFAR1 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 95/367 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.142); catalogued as COSV50054716; called by muse, mutect2, varscan2
- KRT25 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 196/540 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56443537, COSV56444631; called by muse, mutect2, varscan2
- MAGEA6 | c.855A>T p.K285N | Missense Mutation (SNP) | VAF 176/236 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV61449729; called by muse, mutect2, varscan2
- PREX2 | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 141/733 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV55771233; called by muse, mutect2, varscan2
- PTDSS2 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 30/628 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs551825800; called by muse, mutect2
- SLC16A5 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 144/456 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs761272725; called by muse, mutect2, varscan2
- ATAD2B | c.3647A>C p.D1216A | Missense Mutation (SNP) | VAF 179/746 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- C2CD4C | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 94/475 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- DACT1 | c.2113T>C p.Y705H | Missense Mutation (SNP) | VAF 156/474 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.804); called by muse, mutect2
- DNAAF5 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 87/602 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- DNER | c.2007C>A p.Y669* | Nonsense Mutation (SNP) | VAF 32/674 reads (5%) | called by muse, mutect2
- ENTPD1 | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 185/540 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FAM110D | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 176/473 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.226T>G p.S76A | Missense Mutation (SNP) | VAF 221/751 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- KCNJ3 | c.314T>A p.I105N | Missense Mutation (SNP) | VAF 124/543 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- KIF5B | c.1971_1972del p.R658Tfs*11 | Frame Shift Del (DEL) | VAF 145/528 reads (27%) | called by mutect2, pindel, varscan2
- PTPRO | c.3453G>C p.R1151S (on ENST00000281171 / NM_030667.3; = p.R1123S on NM_002848.4) | Missense Mutation (SNP) | VAF 198/758 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); called by muse, varscan2
- RARS2 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 121/367 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1 | c.4508C>T p.T1503I | Missense Mutation (SNP) | VAF 157/731 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XKR6 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 133/482 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ZBTB41 | c.2107C>A p.Q703K | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZSCAN4 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 126/504 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by mutect2, varscan2
- FLYWCH1 | c.1695C>T p.H565= (on ENST00000253928 / NM_001308068.2; = p.H564= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 84/223 reads (38%) | called by muse, mutect2, varscan2
- HYAL2 | c.954G>A p.A318= | Silent (SNP) | VAF 106/489 reads (22%) | catalogued as rs782364122; called by muse, mutect2, varscan2
- KLRF1 | c.93A>T p.S31= | Silent (SNP) | VAF 95/353 reads (27%) | called by muse, mutect2, varscan2
- CORO6 | c.754-199G>T | Intron (SNP) | VAF 231/696 reads (33%) | called by muse, mutect2, varscan2
- DCAF10 | c.-1C>T | 5'UTR (SNP) | VAF 60/176 reads (34%) | catalogued as rs1389374363; called by muse, mutect2, varscan2
- LAIR1 | c.35-72G>A | Intron (SNP) | VAF 23/132 reads (17%) | called by muse, mutect2, varscan2
